Somatic mutation profile of tumor specimen TCGA-KL-8341-01A (aliquot TCGA-KL-8341-01A-11D-2310-10) from TCGA case TCGA-KL-8341, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.2 years (15,045 days).
Specimen TCGA-KL-8341-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d543822c-ba2b-4e07-8486-e2746b145615.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8341-11A (Solid Tissue Normal), aliquot TCGA-KL-8341-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c8034c2-353b-4aa3-8ee5-49265ff1d524

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Nonsense Mutation 3, Splice Site 2, In Frame Del 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOA1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs371084971; called by muse, mutect2, varscan2
- ATP12A | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs763019731; called by muse, mutect2, varscan2
- CCDC154 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as rs550754764; called by muse, mutect2, varscan2
- ERC2 | c.2354_2356del p.E785del | In Frame Del (DEL) | VAF 131/159 reads (82%) | catalogued as rs1229403275; called by pindel, varscan2
- GAK | c.3835-1G>A p.X1279_splice | Splice Site (SNP) | VAF 74/149 reads (50%) | catalogued as COSV100033509; called by muse, mutect2, varscan2
- HEG1 | c.3865G>C p.D1289H | Missense Mutation (SNP) | VAF 81/291 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60765413; called by muse, mutect2, varscan2
- KCNMA1 | c.3407G>T p.G1136V (on ENST00000286628 / NM_001161352.2; = p.G1078V on NM_002247.4) | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54238380; called by muse, mutect2, varscan2
- NDST4 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.586); catalogued as rs1407918167, COSV52114321; called by muse, mutect2
- OR5V1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776638436, COSV65826946; called by muse, mutect2, varscan2
- PALM3 | c.1601C>T p.T534M (on ENST00000340790; = p.T549M on NM_001145028.2) | Missense Mutation (SNP) | VAF 130/269 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs1202322773, COSV54599285; called by muse, mutect2, varscan2
- PARVA | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100616606; called by muse, mutect2
- PCDH1 | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764657895; called by muse, mutect2, varscan2
- PDK2 | c.518-1G>C p.X173_splice | Splice Site (SNP) | VAF 55/60 reads (92%) | catalogued as COSV99142947; called by muse, mutect2, varscan2
- PKD1L2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753639664; called by muse, mutect2
- SLC29A4 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764692318, COSV51875360; called by muse, mutect2, varscan2
- TAS1R1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.58); PolyPhen benign (0.081); catalogued as rs1269844259; called by muse, mutect2, varscan2
- TMEM132C | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs374244452; called by muse, mutect2, varscan2
- TP53 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 42/43 reads (98%) | catalogued as COSV52675742, COSV52676695, COSV53059791; called by muse, mutect2, varscan2
- UBR5 | c.7432C>T p.R2478* | Nonsense Mutation (SNP) | VAF 27/704 reads (4%) | catalogued as COSV55280829; called by muse, mutect2
- UCP2 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 77/149 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs376686039; called by muse, mutect2, varscan2
- ZDBF2 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 71/79 reads (90%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs867975068, COSV65630958; called by muse, mutect2, varscan2
- ACAP3 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, varscan2
- ARHGAP17 | c.1554C>A p.H518Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CAPN3 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CEP290 | c.7192G>A p.E2398K | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- FNDC3A | c.2252A>T p.D751V (on ENST00000492622 / NM_001079673.2; = p.D695V on NM_014923.5) | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH4 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OR4K17 | c.768_775delinsATCTACAT p.F256_I259delinsLSTF | Missense Mutation (ONP) | VAF 57/296 reads (19%) | called by pindel, varscan2*
- OR5AK2 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 204/458 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLC9A8 | c.535-5T>C | Splice Region (SNP) | VAF 67/139 reads (48%) | called by muse, mutect2, varscan2
- TAF9B | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAS2R38 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TSC2 | c.1423A>T p.I475F | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, varscan2
- VWA7 | c.2267A>T p.D756V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZFP62 | c.1783G>T p.E595* (on ENST00000502412 / NM_001377944.1; = p.E562* on NM_152283.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- ADAM28 | c.396T>C p.S132= | Silent (SNP) | VAF 124/194 reads (64%) | catalogued as rs1235408814; called by muse, varscan2
- CABIN1 | c.2655C>T p.L885= | Silent (SNP) | VAF 61/120 reads (51%) | called by muse, mutect2, varscan2
- GALNT2 | c.559T>C p.L187= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100795709; called by muse, mutect2
- GDPGP1 | c.549G>A p.P183= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs373465372; called by muse, mutect2, varscan2
- NR2F1 | c.672G>A p.A224= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs1561524900; called by muse, mutect2, varscan2
- OR13C2 | c.171C>G p.T57= | Silent (SNP) | VAF 49/808 reads (6%) | catalogued as COSV101604872; called by muse, mutect2
- OR5AK2 | c.552T>A p.I184= | Silent (SNP) | VAF 201/452 reads (44%) | called by muse, mutect2, varscan2
- SRGAP1 | c.642T>A p.S214= | Silent (SNP) | VAF 53/159 reads (33%) | called by muse, mutect2, varscan2
- ZC3H3 | c.2055C>T p.G685= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs1408736779, COSV52791792; called by muse, mutect2, varscan2
- ZNF106 | c.1470G>A p.S490= | Silent (SNP) | VAF 119/288 reads (41%) | catalogued as rs766111683, COSV55514901; called by mutect2, varscan2
- ZBTB33 | c.*1470C>T | 3'UTR (SNP) | VAF 56/57 reads (98%) | catalogued as COSV100434171; called by muse, mutect2, varscan2
